CCDI case PBBTGA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a1f47c5c-879e-4ba1-9c41-a098125634c6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Olfactory neurocytoma: ICD-O-3 morphology code: 9521/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 14.8 years (5,418 days).

Biospecimens (3 samples)
- Sample 0DIQZL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR05: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
